Somatic mutation profile of cancer-model specimen HCM-CSHL-0059-C25-85A (3D Organoid; aliquot HCM-CSHL-0059-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0059-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.1 years (29,271 days).
Specimen HCM-CSHL-0059-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01eca97d-aa1b-4059-b70b-6aadfb82012e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0059-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0059-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5842b7b-8c9f-4a4c-bd4e-e19b30fbc714

The open-access MAF lists 94 somatic variants for this specimen: 62 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Nonsense Mutation 4, Intron 4, 5'UTR 3, Splice Site 2, 5'Flank 2, In Frame Del 2, 3'UTR 1, RNA 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 103/222 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.2953G>C p.D985H | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV63021271; called by muse, mutect2, varscan2
- ADAMTS9 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.93); catalogued as rs777954371; called by muse, mutect2, varscan2
- ATP10A | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs767644611, COSV63516289; called by muse, mutect2, varscan2
- BRCC3 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 51/189 reads (27%) | catalogued as rs1351097047; called by muse, mutect2, varscan2
- CERK | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs761416917; called by muse, mutect2, varscan2
- COL3A1 | c.2391+1G>C p.X797_splice | Splice Site (SNP) | VAF 30/450 reads (7%) | catalogued as COSV58596102; called by muse, mutect2
- DCHS1 | c.9224G>A p.G3075D | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.549); catalogued as rs1227831355; called by muse, mutect2, varscan2
- ECEL1 | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs149447864; called by muse, mutect2, varscan2
- F5 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV63125116; called by muse, mutect2, varscan2
- FLG | c.6086C>A p.S2029Y | Missense Mutation (SNP) | VAF 86/2050 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV64238652; called by muse, mutect2
- GGTLC2 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 135/889 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs760624506, COSV67854457; called by muse, mutect2, varscan2
- GRIA1 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1454390322, COSV99599047; called by muse, mutect2, varscan2
- KCNJ16 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 104/187 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751812511, COSV52257673; called by muse, mutect2, varscan2
- KRTAP4-16 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT tolerated (0.18); catalogued as rs773219722; called by muse, mutect2, varscan2
- MAG | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 135/254 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs780660604; called by muse, mutect2, varscan2
- MPDU1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 124/427 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs747197315; called by muse, mutect2, varscan2
- MRGPRD | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369321530, COSV58423252; called by muse, mutect2, varscan2
- MYH13 | c.4810G>A p.V1604M | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs748902789, COSV52842383; called by muse, mutect2, varscan2
- OR2G6 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 105/625 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs138211669; called by muse, mutect2, varscan2
- OR2M2 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62898654; called by muse, mutect2, varscan2
- PAGE1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs782621969, COSV65997959; called by muse, mutect2, varscan2
- PNPLA1 | c.1565C>T p.S522L (on ENST00000394571 / NM_001374623.1; = p.S427L on NM_173676.2) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs747213173, COSV57235238; called by muse, mutect2, varscan2
- PSME4 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.218); catalogued as rs772436206; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RNH1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 92/546 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1346610742; called by muse, mutect2, varscan2
- SMAD4 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV61688387; called by muse, mutect2
- TBKBP1 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1448945115; called by muse, mutect2, varscan2
- TOPAZ1 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs1459664054, COSV59067916; called by muse, mutect2, varscan2
- ZNF300 | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1224316364; called by muse, mutect2, varscan2
- ACOT12 | c.1457T>A p.I486N | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- ADAM22 | c.2338G>T p.D780Y | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ADAMTSL1 | c.2471C>G p.S824* | Nonsense Mutation (SNP) | VAF 66/314 reads (21%) | called by muse, mutect2, varscan2
- AVL9 | c.1210A>T p.T404S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); called by muse, mutect2
- BCOR | c.2479G>T p.A827S | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2
- BTK | c.1908+5G>A | Splice Region (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- CC2D1A | c.833_868del p.G278_V289del | In Frame Del (DEL) | VAF 86/190 reads (45%) | called by mutect2, pindel
- CCER1 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FGF13 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 63/335 reads (19%) | called by muse, mutect2, varscan2
- IGF2R | c.6667G>T p.D2223Y | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQSEC2 | c.3335C>T p.A1112V (on ENST00000642864 / NM_001111125.3; = p.A907V on NM_015075.2) | Missense Mutation (SNP) | VAF 207/428 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IREB2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NGFR | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR4K17 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5T3 | c.815T>A p.M272K | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RAB11FIP2 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- REPS2 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGPD4 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 113/643 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- RNF222 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 23/440 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.07); called by muse, mutect2
- SETD6 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 193/425 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SH2D3A | c.1495C>A p.R499S | Missense Mutation (SNP) | VAF 7/187 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.535); called by muse, mutect2
- SMAD4 | c.1600_1611del p.Q534_D537del | In Frame Del (DEL) | VAF 48/63 reads (76%) | called by mutect2, pindel, varscan2
- SSBP3 | c.566G>A p.R189Q (on ENST00000371320 / NM_145716.4; = p.R169Q on NM_018070.5) | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SUPT20H | c.419G>C p.C140S (on ENST00000350612 / NM_001014286.3; = p.C141S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.471C>A p.S157R (on ENST00000367255 / NM_182961.4; = p.S164R on NM_033071.3) | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1408-13_1414del p.X470_splice | Splice Site (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- WDR41 | c.1261A>T p.T421S | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- YAP1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZFP14 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2
- ZNF100 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- ZNF429 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC131160.1 | c.735C>T p.F245= | Silent (SNP) | VAF 199/549 reads (36%) | called by muse, mutect2, varscan2
- C20orf96 | c.459C>T p.T153= (on ENST00000360321 / NM_153269.3; = p.T152= on NM_080571.1) | Silent (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2
- CABP2 | c.132C>T p.G44= | Silent (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- CALCRL | c.1305C>T p.D435= | Silent (SNP) | VAF 93/202 reads (46%) | called by muse, mutect2, varscan2
- CBLN1 | c.9C>T p.G3= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- CSMD2 | c.3222C>T p.T1074= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs760608600, COSV53880145, COSV99593430; called by muse, mutect2, varscan2
- DOCK2 | c.5106A>T p.T1702= | Silent (SNP) | VAF 132/276 reads (48%) | called by muse, mutect2, varscan2
- FAT2 | c.6918C>T p.D2306= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as rs756953964; called by muse, mutect2, varscan2
- GFRA3 | c.708C>T p.A236= | Silent (SNP) | VAF 107/213 reads (50%) | catalogued as rs1321252020; called by muse, mutect2, varscan2
- GRIN2B | c.3681G>A p.T1227= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs758736358, COSV101663255; called by muse, mutect2, varscan2
- KDM6B | c.3474C>T p.S1158= | Silent (SNP) | VAF 65/539 reads (12%) | catalogued as rs149649053; called by muse, mutect2, varscan2
- MCM4 | c.1917T>G p.T639= | Silent (SNP) | VAF 109/214 reads (51%) | called by muse, mutect2, varscan2
- MMP2 | c.1764C>T p.F588= | Silent (SNP) | VAF 173/373 reads (46%) | called by muse, mutect2, varscan2
- N4BP2L2 | c.1047C>G p.P349= | Silent (SNP) | VAF 92/261 reads (35%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2436G>A p.T812= | Silent (SNP) | VAF 17/259 reads (7%) | catalogued as rs944482151, COSV55198302; called by muse, mutect2
- PRPF8 | c.5958G>T p.L1986= | Silent (SNP) | VAF 14/411 reads (3%) | called by muse, mutect2
- SGO2 | c.2328C>T p.N776= | Silent (SNP) | VAF 55/101 reads (54%) | called by muse, mutect2, varscan2
- SORCS3 | c.219G>A p.A73= | Silent (SNP) | VAF 76/330 reads (23%) | called by muse, varscan2
- UBQLN2 | c.264C>T p.I88= | Silent (SNP) | VAF 19/465 reads (4%) | called by muse, mutect2
- WNT5A | c.927C>T p.C309= | Silent (SNP) | VAF 15/280 reads (5%) | catalogued as COSV52836178, COSV52838417; called by muse, mutect2
- ADGRE4P | n.1801C>T | RNA (SNP) | VAF 51/105 reads (49%) | catalogued as rs761337325; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827501 G>A | 3'Flank (SNP) | VAF 195/399 reads (49%) | catalogued as rs1459556905; called by muse, mutect2, varscan2
- AL359922.1 | c.348-35294_348-35277del | Intron (DEL) | VAF 112/128 reads (88%) | called by mutect2, pindel, varscan2
- CHRND | c.*1215G>A | 3'UTR (SNP) | VAF 32/55 reads (58%) | catalogued as rs754249979; called by muse, mutect2, varscan2
- DUOX2 | c.1235-13C>A | Intron (SNP) | VAF 94/505 reads (19%) | called by muse, mutect2, varscan2
- LGALS13 | c.-18G>A | 5'UTR (SNP) | VAF 181/396 reads (46%) | catalogued as rs753900923, COSV99695047; called by muse, mutect2, varscan2
- RN7SL214P | chr15:77919068 C>T | 5'Flank (SNP) | VAF 312/727 reads (43%) | catalogued as rs751365138; called by muse, mutect2
- VMA21 | chrX:151396944 G>A | 5'Flank (SNP) | VAF 54/290 reads (19%) | called by muse, mutect2, varscan2
- WTAP | c.-463_-462del | 5'UTR (DEL) | VAF 51/126 reads (40%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.-107C>T | 5'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-949C>T | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as rs903305617, COSV100217983; called by muse, mutect2, varscan2
- ZNF565 | c.256+100G>A | Intron (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
